Somatic mutation profile of tumor specimen SM-JU341 (aliquot 7316UP-2110) from CPTAC case C229764, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU341: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c5268b1-4bd8-4396-bc11-9a2eddbfdb1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105275 (Blood Derived Normal), aliquot 7316UP-1359-1105275; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7a44de0-30a0-4fd0-ab99-260f05942a18

The open-access MAF lists 5,059 somatic variants for this specimen: 2,967 protein-altering or splice-affecting, 1,427 silent, 665 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,637, Silent 1,427, Intron 338, Splice Site 136, Nonsense Mutation 118, 3'UTR 110, 5'UTR 73, RNA 73, Splice Region 70, 5'Flank 46, 3'Flank 24, Frame Shift Ins 4.

Variants (750 of 5,059; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6317G>A p.R2106H | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520213, CM159385, COSV64678237; ClinVar: likely pathogenic; called by muse, mutect2
- COLQ | c.393+1G>A p.X131_splice | Splice Site (SNP) | VAF 44/439 reads (10%) | catalogued as rs1085307792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ENG | c.1428+1G>A p.X476_splice | Splice Site (SNP) | VAF 69/562 reads (12%) | catalogued as rs863223542, CS111603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSD3B7 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 95/882 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894518, CM031220, COSV52680560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3656C>T p.T1219I | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750949, CM020039, COSV52276093; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NBN | c.585-1G>A p.X195_splice | Splice Site (SNP) | VAF 8/158 reads (5%) | catalogued as rs1394578008; ClinVar: likely pathogenic; called by muse, mutect2
- PCNT | c.7126C>T p.Q2376* | Nonsense Mutation (SNP) | VAF 87/435 reads (20%) | catalogued as rs1555993038; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.402G>C p.M134I | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1114167676, CM1211213, COSV64291845, COSV64293372, COSV64295066; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC2A1 | c.18+1G>A p.X6_splice | Splice Site (SNP) | VAF 45/359 reads (13%) | catalogued as rs80359841, CS002465, CS101712; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TUBB | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.146); catalogued as rs587777356, CM1212022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs1462098295; called by muse, mutect2
- AAK1 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 44/648 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs771297584; called by muse, mutect2
- ABCC1 | c.3692G>A p.G1231D | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100580329; called by muse, mutect2, varscan2
- ABCC2 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1224922647; called by muse, mutect2, varscan2
- ABCG5 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs758017120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAD10 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1274383922; called by muse, mutect2, varscan2
- ACAD8 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs772448494; called by muse, mutect2
- ACE | c.3125G>A p.G1042D | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV52006393; called by muse, mutect2, varscan2
- ACLY | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs938623544; called by muse, mutect2
- ACSBG1 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs1361410504; called by muse, mutect2, varscan2
- ACSL4 | c.1193C>T p.T398I (on ENST00000340800 / NM_022977.2; = p.T357I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as rs754071672; called by muse, mutect2
- ACTN4 | c.399G>A p.E133= | Splice Region (SNP) | VAF 75/616 reads (12%) | catalogued as COSV53143186; called by muse, mutect2, varscan2
- ADAM17 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as rs1430253235; called by muse, mutect2, varscan2
- ADAM8 | c.639C>T p.F213= | Splice Region (SNP) | VAF 9/78 reads (12%) | catalogued as COSV69864711; called by muse, mutect2
- ADAM9 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 16/278 reads (6%) | catalogued as COSV65946820; called by muse, mutect2
- ADAMTS10 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1555740508; called by muse, mutect2
- ADAT3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60190976; called by muse, mutect2
- ADCY10 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63239181; called by muse, mutect2
- ADGRF3 | c.2242C>T p.L748F (on ENST00000311519 / NM_001145168.1; = p.L549F on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs753122177; called by muse, mutect2, varscan2
- ADGRF4 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs750563328; called by muse, mutect2, varscan2
- ADGRG1 | c.1952-1G>A p.X651_splice | Splice Site (SNP) | VAF 50/538 reads (9%) | catalogued as rs1207621709, COSV100342126; called by muse, mutect2
- ADNP | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 26/199 reads (13%) | catalogued as COSV62427102; called by muse, mutect2, varscan2
- ADTRP | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs1483334930, COSV57644928, COSV57645614; called by muse, mutect2, varscan2
- AFF2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60656822; called by muse, mutect2, varscan2
- AGBL2 | c.2699C>T p.T900I | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs1411813730; called by muse, mutect2
- AGBL4 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV61895323; called by muse, mutect2, varscan2
- AGFG2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 28/560 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53545737; called by muse, mutect2
- AGGF1 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1234035985; called by muse, mutect2, varscan2
- AGL | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54056390, COSV54059023; called by muse, mutect2
- AGRN | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs4970342; called by muse, mutect2, varscan2
- AGRN | c.4826G>A p.G1609D | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs777163307; called by muse, mutect2, varscan2
- AGTPBP1 | c.1750G>A p.G584R (on ENST00000357081 / NM_001330701.2; = p.G544R on NM_015239.2) | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); catalogued as rs780323299; called by muse, mutect2
- AGTR2 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782129199; called by muse, mutect2, varscan2
- AHDC1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1279397466; called by muse, mutect2, varscan2
- AHNAK | c.6784G>A p.E2262K | Missense Mutation (SNP) | VAF 42/515 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.279); catalogued as COSV99949312; called by muse, mutect2
- AHNAK2 | c.6307C>T p.P2103S | Missense Mutation (SNP) | VAF 43/424 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.372); catalogued as rs377027416; called by muse, varscan2
- AIFM1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs1200765574; called by muse, mutect2, varscan2
- AK8 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV53754420; called by muse, mutect2
- AKAP13 | c.5786C>T p.S1929L (on ENST00000394518 / NM_007200.5; = p.S1933L on NM_006738.6) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100774929; called by muse, mutect2, varscan2
- AKAP6 | c.5682G>A p.M1894I | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV55232007; called by muse, mutect2, varscan2
- AL162417.1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1372730216; called by muse, mutect2, varscan2
- ALDH3A2 | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs761486859; called by muse, mutect2
- ALG1 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 48/594 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.527); catalogued as rs748774645; called by muse, mutect2
- ALK | c.3856G>A p.G1286R | Missense Mutation (SNP) | VAF 29/387 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66565679, COSV66592940; called by muse, mutect2
- ALK | c.787+1G>A p.X263_splice | Splice Site (SNP) | VAF 17/245 reads (7%) | catalogued as COSV66558949; called by muse, mutect2
- ALPK1 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs924008753; called by muse, mutect2, varscan2
- ALPK3 | c.2198G>A p.G733D | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs567079042; called by muse, mutect2, varscan2
- AMH | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 103/472 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs558432762; called by muse, mutect2, varscan2
- ANGPTL5 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as rs757290847, COSV99043893; called by muse, mutect2
- ANKFN1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100593329; called by muse, mutect2, varscan2
- ANKIB1 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as rs982695434; called by muse, mutect2, varscan2
- ANKK1 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1266239209; called by muse, mutect2
- ANKRD11 | c.6784G>A p.G2262S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV56356097; called by muse, mutect2, varscan2
- ANKRD11 | c.4940C>T p.P1647L | Missense Mutation (SNP) | VAF 29/373 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs185178673; called by muse, mutect2
- ANKRD28 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1189778027; called by muse, mutect2
- ANKRD30A | c.2648C>T p.A883V (on ENST00000611781; = p.A827V on NM_052997.2) | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.827); catalogued as rs1466882372, COSV64606387; called by muse, mutect2
- ANKRD36 | c.3294+1G>A p.X1098_splice | Splice Site (SNP) | VAF 16/128 reads (13%) | catalogued as rs1392023281; called by muse, mutect2, varscan2
- AOX1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV65984378; called by muse, mutect2, varscan2
- AOX1 | c.3453G>A p.W1151* | Nonsense Mutation (SNP) | VAF 29/188 reads (15%) | catalogued as rs76564086; called by muse, mutect2, varscan2
- AP000812.4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs541690359; called by muse, mutect2, varscan2
- APCDD1L | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as rs770754987; called by muse, mutect2, varscan2
- APOBEC4 | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | catalogued as COSV100426141; called by muse, varscan2
- APPL1 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.358); catalogued as rs755284295; called by muse, mutect2, varscan2
- AR | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as CD000475; called by muse, mutect2
- ARAP3 | c.4402G>A p.G1468S | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.749); catalogued as COSV104381682; called by muse, mutect2, varscan2
- ARFGAP3 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1424089215; called by muse, mutect2, varscan2
- ARFGEF3 | c.4276C>T p.L1426F | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as rs372233023; called by muse, mutect2, varscan2
- ARFIP2 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54448188; called by muse, mutect2
- ARHGAP18 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV63765793; called by muse, mutect2, varscan2
- ARHGAP23 | c.3346G>A p.A1116T | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1334486918; called by muse, mutect2
- ARHGEF11 | c.4253C>T p.A1418V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as rs773257128; called by muse, mutect2, varscan2
- ARHGEF33 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.61); catalogued as rs1267599105; called by muse, mutect2
- ARID2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57599034; called by muse, mutect2, varscan2
- ASAP2 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55634737; called by muse, mutect2, varscan2
- ASCL1 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV57152464; called by muse, mutect2, varscan2
- ASH1L | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs371817037; called by muse, mutect2, varscan2
- ASPRV1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV57227919; called by muse, mutect2
- ASTN1 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1244360548; called by muse, mutect2
- ATAD2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761965716, COSV54881451; called by muse, mutect2
- ATG13 | c.967G>A p.A323T (on ENST00000359513 / NM_001346321.1; = p.A286T on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.524); catalogued as rs745943231; called by muse, mutect2, varscan2
- ATN1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1555143692, COSV63113366; called by muse, mutect2
- ATP10B | c.3230G>A p.G1077D | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1414836377; called by muse, mutect2
- ATP11B | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1248938736; called by muse, mutect2
- ATP13A2 | c.3055G>A p.G1019S | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as rs765075611, COSV100454071; called by muse, mutect2
- ATP1A3 | c.3053-4C>T | Splice Region (SNP) | VAF 32/447 reads (7%) | catalogued as rs1555858732; called by muse, mutect2
- ATP6V1B1 | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs782793493; called by muse, mutect2, varscan2
- ATP8B4 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52708477; called by muse, mutect2
- ATP9B | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 37/412 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs755847576; called by muse, mutect2
- ATRX | c.5188G>A p.A1730T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV64878600; called by muse, mutect2, varscan2
- ATXN10 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 27/387 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs1169006413; called by muse, mutect2
- ATXN2 | c.1981C>T p.P661S (on ENST00000550104; = p.P501S on NM_002973.4) | Missense Mutation (SNP) | VAF 59/412 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as rs1244280752; called by muse, mutect2, varscan2
- ATXN2L | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs573609543; called by muse, mutect2, varscan2
- ATXN7 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 44/592 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs922848988; called by muse, mutect2
- B3GNT8 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs959931361; called by muse, mutect2
- B4GALT5 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as rs1449629020; called by muse, mutect2
- BAG6 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 108/485 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52991245, COSV52991701; called by muse, mutect2, varscan2
- BAHCC1 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as rs782748795; called by muse, mutect2, varscan2
- BAIAP2L1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50056204, COSV99134141; called by muse, mutect2
- BANK1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs186402440; called by muse, mutect2, varscan2
- BATF2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100101835; called by muse, mutect2
- BAZ2A | c.3574C>T p.P1192S | Missense Mutation (SNP) | VAF 38/479 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as rs772984421; called by muse, mutect2
- BAZ2B | c.6158C>T p.T2053I | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV100600543; called by muse, mutect2
- BCL2L12 | c.590-1G>A p.X197_splice | Splice Site (SNP) | VAF 30/329 reads (9%) | catalogued as COSV99881305; called by muse, mutect2
- BEGAIN | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs778462887, COSV100767048; called by mutect2, varscan2
- BEST1 | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 65/346 reads (19%) | catalogued as rs748921533, COSV56444501; called by muse, mutect2, varscan2
- BFSP1 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 39/479 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749440045; called by muse, mutect2
- BMI1 | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as rs1316202687; called by muse, mutect2
- BNC1 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1320001613; called by muse, mutect2
- BOC | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV56355064; called by muse, mutect2
- BOD1L1 | c.7006G>A p.E2336K | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1379470066; called by muse, mutect2, varscan2
- BORCS6 | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 43/739 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as rs1567561158; called by muse, mutect2
- BPIFB6 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1438140465; called by muse, mutect2, varscan2
- BRAF | c.1322C>T p.T441I (on ENST00000288602 / NM_001374244.1; = p.T401I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56074952, COSV56248932; called by muse, mutect2, varscan2
- BRCA1 | c.3160G>A p.V1054M | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs876658479; ClinVar: uncertain significance; called by muse, mutect2
- BRD2 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 28/457 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1231779127; called by muse, mutect2
- C10orf99 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100929357; called by muse, mutect2, varscan2
- C11orf80 | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1414202570; called by muse, mutect2
- C12orf45 | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as rs1452414826; called by muse, mutect2
- C15orf62 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 52/604 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs1201235872; called by muse, mutect2
- C1R | c.337C>T p.P113S (on ENST00000536053 / NM_001354346.2; = p.P99S on NM_001733.7) | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as COSV56925642; called by muse, mutect2, varscan2
- C20orf96 | c.329C>T p.A110V (on ENST00000360321 / NM_153269.3; = p.A109V on NM_080571.1) | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs952711137; called by muse, mutect2, varscan2
- C2CD6 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759109388; called by muse, mutect2, varscan2
- C3 | c.3064G>A p.V1022I | Missense Mutation (SNP) | VAF 51/626 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as rs1322604877; called by muse, mutect2
- C8B | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 33/472 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV64779104; called by muse, mutect2
- CA8 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 37/433 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58772998; called by muse, mutect2
- CABIN1 | c.4648C>T p.R1550C | Missense Mutation (SNP) | VAF 57/508 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149769745; called by muse, mutect2, varscan2
- CACNA1E | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as COSV100702616; called by muse, mutect2
- CACNA1F | c.4418C>T p.A1473V | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557106079; called by muse, mutect2, varscan2
- CACTIN | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); catalogued as rs1355196815, COSV50266557; called by muse, mutect2
- CAMK2B | c.1673+8C>T | Splice Region (SNP) | VAF 24/262 reads (9%) | catalogued as rs1413355652; called by muse, mutect2
- CAMTA2 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 29/307 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs773539959; called by muse, mutect2
- CANT1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764400992; called by muse, mutect2
- CARD10 | c.1065+1G>A p.X355_splice | Splice Site (SNP) | VAF 12/102 reads (12%) | catalogued as rs1173215383; called by muse, mutect2
- CARMIL2 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1334240072; called by muse, mutect2, varscan2
- CARMIL2 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1467907250; called by muse, mutect2
- CASR | c.2119G>A p.A707T (on ENST00000490131; = p.A784T on NM_000388.4) | Missense Mutation (SNP) | VAF 82/705 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56136596; called by muse, mutect2, varscan2
- CATSPERE | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs35715606; called by mutect2, varscan2
- CBARP | c.1120G>A p.E374K (on ENST00000382477; = p.E354K on NM_152769.3) | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as rs1381906449, COSV53068523; called by muse, mutect2, varscan2
- CCDC14 | c.456G>A p.W152* (on ENST00000488653; = p.W104* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 28/178 reads (16%) | catalogued as rs373619932; called by muse, mutect2, varscan2
- CCDC149 | c.1271C>T p.P424L (on ENST00000635206 / NM_001330643.2; = p.P413L on NM_173463.5) | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.028); catalogued as rs1265430517; called by muse, mutect2
- CCDC154 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV66736592; called by muse, mutect2, varscan2
- CCDC166 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as rs1554617029; called by muse, mutect2
- CCDC58 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs1290347483; called by muse, mutect2
- CCDC8 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); catalogued as rs1345376930; called by muse, mutect2, varscan2
- CCDC88C | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1455378745; called by muse, mutect2, varscan2
- CCDC97 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.145); catalogued as rs760667676; called by muse, mutect2
- CCNQ | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs782235940; called by muse, varscan2
- CD163 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV63136157; called by muse, mutect2
- CD1B | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs763137482; called by muse, mutect2
- CDC37L1 | c.539G>A p.R180K | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.241); catalogued as COSV67866101; called by muse, mutect2, varscan2
- CDH15 | c.978+1G>A p.X326_splice | Splice Site (SNP) | VAF 35/464 reads (8%) | catalogued as COSV57021939; called by muse, mutect2
- CDH16 | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 11/127 reads (9%) | catalogued as rs1178580992; called by muse, mutect2
- CDH18 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as rs1280042011; called by muse, mutect2, varscan2
- CDH19 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as COSV50984428; called by muse, mutect2
- CDH19 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767929716; called by mutect2, varscan2
- CDK11B | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1462668002; called by muse, mutect2, varscan2
- CDK18 | c.1013C>T p.P338L (on ENST00000506784 / NM_212503.3; = p.P308L on NM_002596.4) | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1241235480; called by muse, mutect2, varscan2
- CDSN | c.887A>G p.Y296C | Missense Mutation (SNP) | VAF 73/525 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs758844723, COSV99457284; called by muse, mutect2, varscan2
- CENPO | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as rs1208476697; called by muse, mutect2
- CEP112 | c.2864+8C>T | Splice Region (SNP) | VAF 13/113 reads (12%) | catalogued as COSV100439630; called by muse, mutect2, varscan2
- CEP290 | c.3314C>T p.T1105I | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565853251; called by muse, mutect2, varscan2
- CEP85 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53330738; called by muse, mutect2
- CES4A | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58658204; called by muse, mutect2, varscan2
- CFAP251 | c.2731G>A p.G911R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs1427888977; called by muse, mutect2, varscan2
- CFAP44 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs780990198, COSV55610851; called by muse, mutect2, varscan2
- CFAP54 | c.6856G>A p.V2286M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1156630217, COSV61570477; called by muse, mutect2, varscan2
- CH25H | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV64092286; called by muse, mutect2, varscan2
- CHAC1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.055); catalogued as rs1194596095; called by muse, mutect2, varscan2
- CHADL | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1159322609; called by muse, mutect2, varscan2
- CHD1 | c.4210G>A p.E1404K | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); catalogued as COSV52336621; called by muse, mutect2
- CHD1L | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1553973253; called by muse, mutect2, varscan2
- CHD6 | c.5243G>A p.G1748D | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.022); catalogued as rs1250728202; called by muse, mutect2, varscan2
- CHIA | c.985C>T p.Q329* (on ENST00000343320; = p.Q221* on NM_021797.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 45/236 reads (19%) | catalogued as COSV58474271; called by muse, mutect2, varscan2
- CHRM1 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.026); catalogued as rs775393654; called by mutect2, varscan2
- CHRNA4 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV64720298; called by muse, mutect2, varscan2
- CHST14 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs376435449; called by muse, mutect2
- CIC | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50546678; called by muse, mutect2, varscan2
- CIZ1 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.113); catalogued as rs1350554210; called by muse, mutect2
- CKB | c.349-1G>A p.X117_splice | Splice Site (SNP) | VAF 34/225 reads (15%) | catalogued as rs1468777836; called by muse, mutect2, varscan2
- CLDN9 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs1567404565; called by muse, mutect2
- CLPTM1L | c.162+1G>A p.X54_splice | Splice Site (SNP) | VAF 12/146 reads (8%) | catalogued as rs374542300; called by muse, mutect2
- CLSTN1 | c.1871C>T p.T624I (on ENST00000377298 / NM_001009566.3; = p.T614I on NM_014944.4) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV63646552; called by muse, mutect2
- CLTC | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV52250303; called by muse, mutect2
- CMKLR1 | c.133G>A p.V45M (on ENST00000312143 / NM_001142344.2; = p.V43M on NM_004072.3) | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs779039224; called by muse, mutect2, varscan2
- CNDP1 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.161); catalogued as COSV62595821; called by muse, mutect2
- CNGB3 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1386894445, COSV100182795; called by muse, mutect2, varscan2
- CNKSR1 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 42/391 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs761320294, COSV64164015; called by muse, mutect2, varscan2
- CNOT4 | c.1349G>A p.G450D (on ENST00000315544 / NM_001190848.1; = p.G447D on NM_013316.4) | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as rs913822014; called by muse, mutect2
- CNPPD1 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs968254835; called by muse, mutect2
- CNR1 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs757730631, COSV100759262; called by muse, mutect2, varscan2
- COCH | c.1447G>A p.E483K (on ENST00000216361 / NM_001347720.1; = p.E418K on NM_004086.3) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53550721, COSV53550761; called by muse, mutect2, varscan2
- COG2 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as rs774526575; called by muse, mutect2
- COG4 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 33/334 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs780209257; called by muse, mutect2, varscan2
- COL11A2 | c.2790+1G>A p.X930_splice (on ENST00000341947 / NM_080680.3; = p.X823_splice on NM_080679.2) | Splice Site (SNP) | VAF 36/469 reads (8%) | catalogued as COSV59495126; called by muse, mutect2
- COL3A1 | c.3584C>T p.P1195L | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV58585598; called by muse, mutect2, varscan2
- COL4A1 | c.2758C>T p.P920S | Missense Mutation (SNP) | VAF 72/578 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs142828583; called by muse, mutect2, varscan2
- COL4A3 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 33/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67416146; called by muse, mutect2
- COL4A5 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM085960; called by muse, mutect2, varscan2
- COL4A6 | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV57875408; called by muse, mutect2, varscan2
- COL5A3 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs1260436274; called by muse, mutect2, varscan2
- COL7A1 | c.8226+1G>A p.X2742_splice | Splice Site (SNP) | VAF 40/144 reads (28%) | catalogued as CD095172; called by muse, mutect2, varscan2
- COL7A1 | c.7521+1G>A p.X2507_splice | Splice Site (SNP) | VAF 29/148 reads (20%) | catalogued as rs1560200657; called by muse, mutect2, varscan2
- COL9A1 | c.1948C>T p.L650F | Missense Mutation (SNP) | VAF 55/523 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.565); catalogued as rs1269618884, COSV57884268; called by muse, mutect2, varscan2
- COMMD8 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV101055766; called by muse, mutect2, varscan2
- COP1 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100442836; called by muse, mutect2, varscan2
- CORO1C | c.855G>A p.K285= | Splice Region (SNP) | VAF 21/92 reads (23%) | catalogued as rs1185037194; called by muse, mutect2, varscan2
- CORO2B | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV55951975; called by muse, mutect2
- CPLANE2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs868709955; called by muse, mutect2, varscan2
- CPNE2 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs866046163; called by muse, mutect2
- CPSF2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.817); catalogued as COSV54099328; called by muse, mutect2, varscan2
- CRB1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66332235, COSV66332501; called by muse, mutect2, varscan2
- CREB3L2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/224 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1395366298, COSV57800550; called by muse, mutect2
- CREBBP | c.4606G>A p.E1536K | Missense Mutation (SNP) | VAF 31/385 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1567269379; called by muse, mutect2
- CREBBP | c.4418C>T p.A1473V | Missense Mutation (SNP) | VAF 44/406 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52120090; called by muse, mutect2, varscan2
- CROCC | c.2395G>A p.V799M | Missense Mutation (SNP) | VAF 36/628 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs1215294097; called by muse, mutect2
- CROCC | c.4499C>T p.P1500L | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs748575001; called by muse, mutect2, varscan2
- CRYGC | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 81/438 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs544008612, COSV52204963; called by muse, mutect2, varscan2
- CSAD | c.1033G>A p.V345M (on ENST00000444623 / NM_001244705.2; = p.V372M on NM_015989.5) | Missense Mutation (SNP) | VAF 32/572 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV57242181; called by muse, mutect2
- CSNK1A1L | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 67/366 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); catalogued as rs368855406; called by muse, mutect2, varscan2
- CST1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs754531104; called by muse, mutect2, varscan2
- CXorf66 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100983826, COSV100983949; called by muse, mutect2, varscan2
- CYFIP1 | c.3146G>A p.R1049K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV57408220; called by muse, mutect2
- CYLC1 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as COSV61412049; called by muse, mutect2, varscan2
- CYP11A1 | c.1434+1G>A p.X478_splice | Splice Site (SNP) | VAF 32/436 reads (7%) | catalogued as COSV99166283; called by muse, mutect2
- DACH1 | c.1891G>A p.V631I (on ENST00000619232 / NM_001366712.1; = p.V377I on NM_004392.6) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57522030; called by muse, mutect2, varscan2
- DACT1 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 46/516 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.099); catalogued as rs1369377514; called by muse, mutect2
- DACT2 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1198336544; called by muse, mutect2, varscan2
- DAOA | c.44+1G>A p.X15_splice | Splice Site (SNP) | VAF 14/220 reads (6%) | catalogued as COSV100298899; called by muse, mutect2
- DCN | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV50007851, COSV99271940; called by muse, mutect2
- DDC | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 44/519 reads (8%) | catalogued as rs1306265578; called by muse, mutect2
- DDX11 | c.2212G>A p.E738K (on ENST00000545668 / NM_152438.2; = p.E688K on NM_004399.3) | Missense Mutation (SNP) | VAF 101/440 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446735610; called by muse, mutect2, varscan2
- DDX46 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV100844908, COSV62799795; called by muse, mutect2
- DDX59 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58752814; called by muse, mutect2
- DEF6 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV57355046; called by muse, mutect2, varscan2
- DENND1C | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 26/413 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1231986466, COSV57568682; called by muse, mutect2
- DGKA | c.708C>T p.N236= | Splice Region (SNP) | VAF 13/117 reads (11%) | catalogued as rs758503630; called by muse, mutect2, varscan2
- DHRS4L2 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs1237321013; called by muse, mutect2
- DHX33 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56580191; called by muse, mutect2, varscan2
- DICER1 | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV58628722; called by muse, mutect2, varscan2
- DIDO1 | c.4858G>A p.A1620T | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs771766063; called by muse, mutect2, varscan2
- DIP2C | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as COSV55156216; called by muse, mutect2
- DIPK1B | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.065); catalogued as rs893780766; called by muse, mutect2
- DMRTC2 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99523294; called by muse, mutect2
- DMXL2 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV51842376; called by muse, mutect2, varscan2
- DNAH2 | c.4057G>A p.E1353K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs372974924, COSV66718453; called by mutect2, varscan2
- DNAH3 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs751698402; called by muse, varscan2
- DNAH6 | c.7877G>A p.G2626E | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.566); catalogued as COSV52881594; called by muse, mutect2
- DNAJB6 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1563137106; called by muse, mutect2, varscan2
- DNAJC5B | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 88/477 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52535665; called by muse, mutect2, varscan2
- DNASE2B | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 25/199 reads (13%) | catalogued as rs199881802; called by muse, mutect2, varscan2
- DNHD1 | c.6053C>T p.T2018I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1287613931; called by muse, varscan2
- DNHD1 | c.6059C>T p.T2020I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs1057495175; called by muse, varscan2
- DNHD1 | c.11632C>T p.P3878S | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs1232660118; called by muse, mutect2, varscan2
- DNM2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 51/500 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV58965232; called by muse, varscan2
- DNMT1 | c.4264G>A p.A1422T | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as rs1158543755; called by muse, mutect2
- DOCK3 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1169551198; called by muse, mutect2
- DOCK4 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV101447909; called by muse, mutect2
- DOCK5 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.56); catalogued as COSV52415407; called by muse, mutect2, varscan2
- DOCK8 | c.6109G>A p.A2037T | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as rs866262584; called by muse, mutect2, varscan2
- DOT1L | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV67110732; called by muse, mutect2
- DSG2 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1156468696, COSV55197790; called by muse, mutect2
- DUOXA1 | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV50993030; called by muse, mutect2
- DUSP2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.567); catalogued as rs1242351072; called by muse, mutect2, varscan2
- DVL1 | c.1610G>A p.G537D (on ENST00000378888 / NM_001330311.2; = p.G512D on NM_004421.3) | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.361); catalogued as rs760842641; called by muse, varscan2
- DYNC1LI1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1411141475; called by muse, mutect2, varscan2
- DYNC2H1 | c.7591G>A p.A2531T | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100518193; called by muse, mutect2
- E2F8 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV51461857; called by muse, mutect2, varscan2
- EFCAB8 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV68700997; called by muse, mutect2
- EFHB | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.396); catalogued as COSV55547870; called by muse, mutect2, varscan2
- EFR3B | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV53120125; called by muse, mutect2, varscan2
- EIF2B4 | c.283C>T p.R95W (on ENST00000347454 / NM_001034116.2; = p.R94W on NM_015636.3) | Missense Mutation (SNP) | VAF 58/786 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs756288383, COSV99277315; called by muse, mutect2
- ELF4 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.88); catalogued as rs1364932790, COSV57453146; called by muse, mutect2, varscan2
- ELFN1 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774563944, COSV70035105; called by muse, mutect2, varscan2
- ELN | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 90/601 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1216302521; called by muse, mutect2, varscan2
- EPHA1 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs770297450; called by mutect2, varscan2
- EPHA10 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57624618; called by muse, mutect2
- EPHA5 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV56664667; called by muse, mutect2, varscan2
- EPHA8 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1227374950; called by muse, varscan2
- EPHB4 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs920850385; called by muse, mutect2
- EPPK1 | c.5827C>T p.P1943S | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1456195229; called by muse, mutect2
- ERN1 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 45/445 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70501206; called by muse, mutect2
- ERVV-2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 59/455 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); catalogued as rs1158398547; called by muse, mutect2, varscan2
- ESR1 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 55/397 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.041); catalogued as rs201118302, COSV52783458; called by muse, mutect2, varscan2
- ESYT1 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 53/520 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.021); catalogued as COSV99919670; called by muse, mutect2, varscan2
- EXPH5 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV56198909; called by muse, mutect2, varscan2
- EYA4 | c.581-1G>A p.X194_splice | Splice Site (SNP) | VAF 46/484 reads (10%) | catalogued as COSV100765069, COSV62058516; called by muse, mutect2
- EZHIP | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as rs372074283; called by muse, mutect2, varscan2
- FABP6 | c.333G>A p.E111= | Splice Region (SNP) | VAF 44/372 reads (12%) | catalogued as rs1318079173; called by muse, mutect2, varscan2
- FAM110A | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1213567847; called by muse, mutect2
- FAM135B | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV52704222, COSV99422994; called by muse, mutect2
- FAM160A2 | c.1481C>A p.P494H (on ENST00000449352 / NM_001098794.2; = p.P508H on NM_032127.4) | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56412305; called by muse, mutect2
- FAM71E2 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 50/618 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs989423626; called by muse, mutect2
- FANCA | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 98/511 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs148419748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCF | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 49/708 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs149687560; called by muse, mutect2
- FASTK | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as rs1473315811; called by muse, mutect2
- FAT2 | c.6805C>T p.P2269S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs764158288, COSV55815572; called by muse, mutect2, varscan2
- FAT3 | c.8593G>A p.A2865T | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53183080; called by muse, mutect2
- FAT4 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs771598800; called by mutect2, varscan2
- FAT4 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1193758539; called by muse, mutect2
- FBN1 | c.246C>T p.V82= | Splice Region (SNP) | VAF 34/438 reads (8%) | catalogued as COSV57323203; called by muse, mutect2
- FBXO31 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100291595; called by muse, mutect2, varscan2
- FBXO40 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs986296977, COSV100573301; called by muse, mutect2, varscan2
- FBXO40 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV100572976; called by muse, mutect2, varscan2
- FCGBP | c.11426C>T p.T3809I | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs748807019; called by muse, mutect2
- FCRL3 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.409); catalogued as COSV100943376; called by muse, mutect2, varscan2
- FER1L5 | c.1981G>A p.A661T (on ENST00000623019; = p.A666T on NM_001293083.2) | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV101330844; called by muse, mutect2
- FGB | c.833-1G>A p.X278_splice | Splice Site (SNP) | VAF 34/382 reads (9%) | catalogued as COSV57418688; called by muse, mutect2
- FGFBP1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV52586857; called by muse, mutect2, varscan2
- FHDC1 | c.1967G>A p.G656D | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs368037557; called by muse, mutect2
- FIGNL1 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100794969; called by muse, mutect2, varscan2
- FILIP1 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.794); catalogued as COSV52723403; called by muse, mutect2, varscan2
- FKBP6 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 31/561 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs374791338, COSV52720273, COSV52721341; called by muse, mutect2
- FLNC | c.4963G>A p.G1655S | Missense Mutation (SNP) | VAF 85/461 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV57958685; called by muse, mutect2, varscan2
- FMNL2 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV99979087; called by muse, mutect2
- FMOD | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs752935066; called by muse, mutect2, varscan2
- FOLH1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57052446; called by muse, mutect2, varscan2
- FOXRED2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs577110470; called by muse, mutect2, varscan2
- FPGS | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100785278; called by muse, mutect2, varscan2
- FSHR | c.2003G>A p.R668K | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1182666505, COSV100438348; called by muse, mutect2, varscan2
- GABRP | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54662872; called by muse, varscan2
- GAD1 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV60152516; called by muse, mutect2
- GAK | c.3238C>T p.P1080S | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV58510611; called by muse, mutect2
- GALNT10 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1205250896; called by muse, mutect2, varscan2
- GALNT14 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140948320; called by muse, mutect2, varscan2
- GAS2L3 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs1452071194; called by muse, mutect2, varscan2
- GATA1 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as CS063314, COSV64961387, COSV64961668; called by muse, mutect2, varscan2
- GATB | c.1331G>A p.S444N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs761753310; called by muse, mutect2
- GBP2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65069911; called by muse, mutect2, varscan2
- GCFC2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58079561; called by muse, mutect2
- GFOD1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV64955144; called by muse, mutect2
- GFPT2 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.219); catalogued as rs747062916; called by muse, mutect2, varscan2
- GGA2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs865953469; called by muse, mutect2
- GIGYF1 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as rs1262173546; called by muse, mutect2, varscan2
- GIGYF2 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65247299; called by muse, mutect2
- GIMAP4 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.058); catalogued as rs909825003, COSV55431136; called by muse, mutect2, varscan2
- GLB1L2 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1442946444, COSV60279138; called by muse, mutect2
- GLYATL3 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1366139244; called by muse, mutect2, varscan2
- GNAS | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 36/489 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs747005037, COSV58333403, COSV58347402; called by muse, mutect2
- GOLGA1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1051814800; called by muse, mutect2, varscan2
- GP1BB | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 140/552 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs1237023924; called by muse, mutect2, varscan2
- GPATCH2 | c.1206+6G>T | Splice Region (SNP) | VAF 35/330 reads (11%) | catalogued as rs1343061034; called by muse, varscan2
- GPATCH8 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV59194383; called by muse, mutect2
- GPC6 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as COSV65526064; called by muse, mutect2, varscan2
- GPN1 | c.350+1G>A p.X117_splice | Splice Site (SNP) | VAF 11/106 reads (10%) | catalogued as rs1558486167; called by muse, mutect2, varscan2
- GPN3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1208040516, COSV99959985; called by muse, mutect2
- GPR146 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV99866339; called by muse, mutect2, varscan2
- GPR17 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55757228; called by muse, mutect2
- GPR179 | c.3854G>A p.G1285D (on ENST00000621958; = p.G1284D on NM_001004334.4) | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1349066788; called by muse, mutect2, varscan2
- GPR25 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1470587407, COSV100421750; called by muse, varscan2
- GPR85 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51783474, COSV51785882; called by muse, mutect2, varscan2
- GPRC6A | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372617351, COSV59953010; called by muse, mutect2
- GPRIN1 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs760127762; called by muse, mutect2, varscan2
- GPRIN2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs782670478; called by muse, mutect2
- GPRIN3 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1242936299; called by muse, mutect2
- GPT | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370834938; called by muse, mutect2
- GREB1 | c.4960G>A p.V1654M | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.298); catalogued as rs371617426; called by muse, mutect2
- GRIK5 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV53477978; called by muse, mutect2
- GRIN2D | c.3479G>A p.G1160D | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as rs1422044339; called by muse, mutect2
- GRK7 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1363422538; called by muse, mutect2, varscan2
- GRK7 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 49/491 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99380238; called by muse, mutect2
- GSG1L | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1276878770; called by muse, mutect2
- GTPBP3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs369410374; called by muse, mutect2, varscan2
- GUCY2C | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as rs1159423242; called by muse, mutect2, varscan2
- GZMM | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 29/343 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs778944154; called by muse, mutect2
- H2BC13 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.991); catalogued as COSV100704403; called by muse, mutect2
- H3C7 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 107/444 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV55099645; called by muse, mutect2, varscan2
- HBEGF | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.293); catalogued as COSV50183609; called by muse, mutect2, varscan2
- HCRTR2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 56/588 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as rs1286164930, COSV63793572; called by muse, mutect2
- HEATR3 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 53/491 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867437937; called by muse, mutect2, varscan2
- HEATR5B | c.4613G>A p.W1538* | Nonsense Mutation (SNP) | VAF 34/529 reads (6%) | catalogued as rs1347152120; called by muse, mutect2
- HECTD4 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV101106946; called by muse, mutect2, varscan2
- HEMGN | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV52326197; called by muse, mutect2
- HERC2 | c.7111C>T p.P2371S | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as rs776189974; called by muse, mutect2, varscan2
- HIPK4 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52519235; called by muse, mutect2, varscan2
- HIVEP1 | c.1979G>A p.G660E | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs964651822; called by muse, mutect2, varscan2
- HIVEP2 | c.4469C>T p.P1490L | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99174214; called by muse, mutect2
- HIVEP2 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1221838320, COSV50008408; called by muse, mutect2, varscan2
- HLA-DQA2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 120/786 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs755273163; called by muse, varscan2
- HMGCLL1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs749751733; called by mutect2, varscan2
- HNRNPA2B1 | c.1000+1G>A p.X334_splice (on ENST00000354667 / NM_031243.3; = p.X322_splice on NM_002137.4) | Splice Site (SNP) | VAF 10/101 reads (10%) | catalogued as COSV61159873; called by muse, mutect2, varscan2
- HOXA9 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as rs1412102757; called by muse, mutect2, varscan2
- HOXB3 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.354); catalogued as rs964014129; called by muse, mutect2, varscan2
- HPS1 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 120/505 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57269241; called by muse, mutect2, varscan2
- HS3ST5 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as COSV57136130; called by muse, mutect2
- HSD11B2 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 38/562 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs913489956; called by muse, mutect2
- HSF1 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.055); catalogued as rs1280144245; called by muse, mutect2, varscan2
- HSF4 | c.1285C>T p.P429S (on ENST00000521374 / NM_001040667.3; = p.P399S on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/601 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755399782; called by muse, mutect2
- HSPG2 | c.4279G>A p.G1427S | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs374019569; called by muse, mutect2
- HSPG2 | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 53/462 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs757543686; called by muse, mutect2, varscan2
- HTRA2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV51206238; called by mutect2, varscan2
- HYOU1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101345606; called by muse, mutect2, varscan2
- IDH3G | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs782671638, COSV54207621; called by muse, mutect2, varscan2
- IFNL2 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV59593857, COSV59593993; called by muse, mutect2, varscan2
- IFT43 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs767257593; called by muse, mutect2
- IFT88 | c.425+1G>A p.X142_splice (on ENST00000319980 / NM_001318493.2; = p.X133_splice on NM_006531.5 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 34/158 reads (22%) | catalogued as rs948410524; called by muse, mutect2, varscan2
- IGKV1D-43 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 58/720 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs370949885; called by muse, mutect2
- IGLL1 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.459); catalogued as rs766536756; called by muse, mutect2
- IGSF1 | c.3566G>A p.G1189D | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV63838003; called by muse, mutect2, varscan2
- IGSF9B | c.3145G>A p.G1049R | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs1403149188, COSV58068118; called by muse, mutect2, varscan2
- IKBKB | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV60600216; called by muse, mutect2, varscan2
- IKBKB | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 20/256 reads (8%) | catalogued as rs768351634; called by muse, mutect2
- IL18RAP | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826052, COSV51828701; called by muse, mutect2, varscan2
- IL27 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100112566; called by muse, mutect2, varscan2
- IL36B | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs779061101; called by muse, mutect2, varscan2
- IL4I1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1012762903; called by muse, mutect2
- IL7R | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV100286720; called by muse, mutect2
- INHBE | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 77/454 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs1214664886; called by muse, mutect2, varscan2
- INPPL1 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as rs1426824226; called by muse, mutect2
- INSIG1 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs897710551; called by muse, mutect2, varscan2
- IRS2 | c.2333G>A p.G778D | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.543); catalogued as rs1471195201; called by muse, mutect2
- ITGA1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99251491; called by muse, mutect2
- ITGA2B | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as rs1393770089; called by muse, mutect2
- ITIH1 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs754266797, COSV56258851; called by muse, mutect2
- ITIH2 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs148172382; called by muse, mutect2, varscan2
- ITPKB | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as COSV55263679; called by muse, mutect2
- JAG1 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1275874823; called by muse, mutect2
- JMJD6 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs1408853901; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV59827402, COSV59828667; called by muse, mutect2, varscan2
- KANK2 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV62007402; called by muse, mutect2, varscan2
- KANK2 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV62007860; called by muse, mutect2
- KCNA7 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV55504041; called by muse, mutect2
- KCNB2 | c.2629G>A p.D877N | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.152); catalogued as rs867679827, COSV73051129, COSV73052870; called by muse, mutect2
- KCNH7 | c.3248C>T p.P1083L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.307); catalogued as rs1319348402; called by muse, mutect2, varscan2
- KCNJ12 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs781983715, COSV59166412; called by muse, varscan2
- KCNS3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.248); catalogued as COSV58406530; called by muse, mutect2
- KCTD9 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); catalogued as COSV55341698; called by muse, mutect2
- KDM5A | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 36/383 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV101238573; called by muse, mutect2
- KDM6A | c.384+1G>A p.X128_splice | Splice Site (SNP) | VAF 10/109 reads (9%) | catalogued as COSV65047173, COSV65047945; called by muse, mutect2
- KDR | c.3839C>T p.P1280L | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV55764028; called by muse, mutect2, varscan2
- KHK | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 74/580 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs1464530815; called by muse, mutect2, varscan2
- KIAA0408 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV64115887; called by muse, mutect2
- KIF1A | c.3379G>A p.G1127R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395195328; called by muse, varscan2
- KIF22 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV50715457; called by muse, mutect2
- KIF3B | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.055); catalogued as rs776674166; called by muse, varscan2
- KIF5C | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs778563315; called by muse, mutect2
- KIFC2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as COSV56761780; called by muse, mutect2, varscan2
- KLC2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 28/389 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57581729; called by muse, mutect2
- KLF1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 76/974 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53434647, COSV53436072; called by muse, mutect2
- KLHDC7A | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV68770085; called by muse, mutect2
- KLHDC7B | c.1303C>T p.P435S (on ENST00000395676; = p.P1076S on NM_138433.5) | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464621584; called by muse, mutect2, varscan2
- KLHL31 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1382523953; called by muse, mutect2
- KLHL7 | c.1531G>A p.V511I (on ENST00000339077 / NM_001031710.3; = p.V463I on NM_018846.5) | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as rs1197975920; called by muse, mutect2, varscan2
- KLK2 | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs751806019; called by muse, mutect2, varscan2
- KLK9 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs933866307, COSV51593333; called by muse, mutect2
- KMT2A | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63292523; called by muse, mutect2, varscan2
- KMT2A | c.7588G>A p.E2530K | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV63292003; called by muse, mutect2
- KMT2C | c.1289G>A p.W430* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100076359, COSV100077754; called by muse, mutect2
- KRT23 | c.798+1G>A p.X266_splice | Splice Site (SNP) | VAF 32/113 reads (28%) | catalogued as COSV52929144; called by muse, mutect2, varscan2
- KRT6A | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 90/745 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs759307145, COSV58106799; called by muse, mutect2, varscan2
- KRTAP10-1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs782163395; called by muse, mutect2
- KRTAP27-1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765681661, COSV67000900, COSV67001054; called by muse, mutect2, varscan2
- KRTAP4-7 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 93/492 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV66951930; called by muse, mutect2, varscan2
- KSR1 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 41/191 reads (21%) | catalogued as COSV99261147; called by muse, mutect2, varscan2
- LACRT | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.205); catalogued as rs763824465, COSV57688909; called by muse, mutect2, varscan2
- LAMA5 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53358205; called by muse, mutect2
- LAMB2 | c.3607G>A p.D1203N | Missense Mutation (SNP) | VAF 94/469 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1489480937; called by muse, mutect2, varscan2
- LAMTOR3 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1448741915; called by muse, mutect2, varscan2
- LANCL1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs764020159; called by muse, mutect2, varscan2
- LATS1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.027); catalogued as COSV53589183; called by muse, mutect2, varscan2
- LAYN | c.850G>A p.G284R (on ENST00000375615 / NM_001258390.1; = p.G276R on NM_178834.5) | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV65105216; called by muse, mutect2, varscan2
- LCMT2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as rs142722274; called by muse, mutect2, varscan2
- LGALS12 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55369713; called by muse, mutect2, varscan2
- LGALS16 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs764476165; called by muse, mutect2, varscan2
- LGR5 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.104); catalogued as COSV57002021, COSV57004906; called by muse, mutect2, varscan2
- LHFPL6 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65449948; called by muse, mutect2
- LILRA6 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 105/1011 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54435860; called by muse, mutect2, varscan2
- LLGL1 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1226054204; called by muse, mutect2
- LMBR1L | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs1323161993; called by muse, mutect2
- LMOD3 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 31/414 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770796044; called by muse, mutect2
- LOXHD1 | c.5302G>A p.D1768N (on ENST00000642948; = p.D1706N on NM_144612.7) | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV56068935; called by muse, mutect2, varscan2
- LOXHD1 | c.4076C>T p.A1359V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1384253106; called by muse, mutect2, varscan2
- LOXL2 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101207766; called by muse, mutect2
- LPIN2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55241315; called by muse, mutect2, varscan2
- LRP2 | c.13840C>T p.P4614S | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1222400860, COSV99787037; called by muse, mutect2
- LRP4 | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs776547887; called by muse, varscan2
- LRP8 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60099258; called by muse, mutect2
- LRRC17 | c.-141+1G>A | Splice Site (SNP) | VAF 45/312 reads (14%) | catalogued as rs759963809; called by muse, mutect2, varscan2
- LRRC29 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs376894911; called by muse, mutect2, varscan2
- LRRC37A3 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 72/1570 reads (5%) | catalogued as rs1244044234; called by muse, mutect2
- LRRC4 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.292); catalogued as rs1412590926; called by muse, mutect2
- LRRC45 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.249); catalogued as rs1321640720; called by muse, mutect2, varscan2
- LRRC4C | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53430803; called by muse, mutect2, varscan2
- LRRK2 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1259652933; called by muse, mutect2, varscan2
- LRRN3 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs771295780; called by muse, mutect2, varscan2
- LSS | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs763440644; called by muse, mutect2, varscan2
- LUZP2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV61196874; called by muse, mutect2
- LYPD2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1230443006; called by muse, mutect2, varscan2
- MACF1 | c.6433G>A p.E2145K | Missense Mutation (SNP) | VAF 31/125 reads (25%) | catalogued as rs1168393704; called by muse, mutect2, varscan2
- MACF1 | c.9164C>T p.P3055L | Missense Mutation (SNP) | VAF 34/147 reads (23%) | catalogued as rs1456618937, COSV99246167; called by muse, mutect2, varscan2
- MACF1 | c.19181G>A p.R6394K (on ENST00000372915; = p.R4439K on NM_012090.5) | Missense Mutation (SNP) | VAF 18/197 reads (9%) | catalogued as rs746072417; called by muse, mutect2
- MAP11 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1164149409; called by muse, mutect2, varscan2
- MAP1S | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 58/430 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as COSV60724999; called by muse, varscan2
- MAP2K1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.086); catalogued as COSV61070339; called by muse, mutect2
- MAP2K3 | c.212G>A p.G71D (on ENST00000342679 / NM_145109.3; = p.G42D on NM_002756.4) | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752806793; called by muse, varscan2
- MAP7 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1473859887; called by muse, mutect2
- MAPK12 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 31/395 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1300419273; called by muse, mutect2
- MAPK14 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100004786; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 59/620 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776306021; called by muse, mutect2
- MAPT | c.1216C>T p.P406S (on ENST00000262410 / NM_001377265.1; = p.P331S on NM_016835.4) | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs747036491; called by muse, mutect2
- MARCHF2 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53104084; called by muse, mutect2
- MARS2 | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs775077650, COSV56572262; called by muse, mutect2
- MATN2 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 49/350 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1270204309; called by muse, mutect2, varscan2
- MBOAT1 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as rs770256909; called by mutect2, varscan2
- MBTPS1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 25/401 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58571117; called by muse, mutect2
- MC4R | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs939392402, COSV100236171; called by muse, mutect2
- MCAM | c.1562C>T p.T521I | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV99875709; called by muse, mutect2
- MCM3AP | c.4300G>A p.G1434S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250976825; called by muse, mutect2
- MCM6 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs1329164092; called by muse, mutect2, varscan2
- MCM7 | c.987G>A p.E329= | Splice Region (SNP) | VAF 21/268 reads (8%) | catalogued as COSV57997871; called by muse, mutect2
- MCOLN1 | c.1134G>A p.K378= | Splice Region (SNP) | VAF 71/418 reads (17%) | catalogued as rs202000556, COSV51180607; called by muse, mutect2, varscan2
- MED23 | c.2084C>T p.T695I | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as rs113634905; called by muse, mutect2, varscan2
- MEGF8 | c.4534G>A p.G1512S (on ENST00000251268 / NM_001271938.2; = p.G1445S on NM_001410.3) | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52080388; called by muse, mutect2
- MEIS2 | c.1036+1G>A p.X346_splice (on ENST00000561208 / NM_170675.5; = p.X333_splice on NM_002399.3) | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV54936103; called by muse, mutect2
- MEN1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 29/344 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as CM021287, COSV53642987, COSV53646656; called by muse, mutect2
- MEPCE | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52769612; called by muse, mutect2
- MFSD12 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV100281371; called by muse, mutect2
- MGA | c.5017G>A p.V1673I | Missense Mutation (SNP) | VAF 67/369 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1387971639; called by muse, mutect2, varscan2
- MGA | c.5647G>A p.A1883T (on ENST00000219905 / NM_001164273.1; = p.A1674T on NM_001080541.2) | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs370050031; called by muse, mutect2, varscan2
- MGARP | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as rs761832021; called by muse, mutect2
- MGLL | c.629G>A p.G210D (on ENST00000398104 / NM_001003794.2; = p.G220D on NM_007283.6) | Missense Mutation (SNP) | VAF 57/482 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV99412518; called by muse, mutect2, varscan2
- MICAL2 | c.4856C>T p.P1619L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as rs1372430786; called by muse, mutect2, varscan2
- MIER2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV53397581; called by muse, varscan2
- MINAR1 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV59584731; called by muse, mutect2, varscan2
- MINDY2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV57507081; called by muse, mutect2, varscan2
- MINDY4 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.054); catalogued as rs201132541; called by muse, varscan2
- MIOX | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs769242335, COSV53312893; called by muse, mutect2, varscan2
- MLANA | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101199968; called by muse, mutect2
- MLXIPL | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as rs899641728; called by muse, mutect2
- MMD2 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.466); catalogued as rs1318481797; called by muse, mutect2
- MMRN1 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 31/149 reads (21%) | catalogued as rs1285256374; called by muse, mutect2, varscan2
- MN1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.116); catalogued as rs1251099459; called by muse, mutect2, varscan2
- MPST | c.733G>A p.V245M (on ENST00000341116 / NM_001369904.2; = p.V265M on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as rs762471056; called by muse, mutect2, varscan2
- MRNIP | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs777834009; called by muse, mutect2, varscan2
- MROH1 | c.4865C>T p.P1622L | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs992300324; called by muse, mutect2, varscan2
- MRPL46 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56899690; called by muse, mutect2, varscan2
- MSH4 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV54200448; called by muse, mutect2, varscan2
- MSH6 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 109/491 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs758432113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MST1R | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs763045729, COSV56569039; called by muse, mutect2
- MST1R | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV56573374; called by muse, mutect2
- MSX2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs781619692, COSV53326649; called by muse, mutect2, varscan2
- MTMR11 | c.1306C>T p.L436F (on ENST00000439741 / NM_001145862.2; = p.L364F on NM_181873.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54967001; called by muse, mutect2
- MTMR11 | c.706C>T p.P236S (on ENST00000439741 / NM_001145862.2; = p.P164S on NM_181873.3) | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63807136; called by muse, mutect2
- MTMR8 | c.2081G>A p.S694N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs778850947, COSV66392160; called by muse, mutect2, varscan2
- MTUS1 | c.3472G>A p.D1158N (on ENST00000262102 / NM_001363061.1; = p.D324N on NM_020749.4) | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50555028; called by muse, mutect2, varscan2
- MUC16 | c.41680C>T p.P13894S | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.992); catalogued as rs953854315; called by muse, mutect2, varscan2
- MUC16 | c.33799G>A p.V11267I | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.148); catalogued as rs1163348408; called by muse, mutect2
- MUC16 | c.24728C>T p.T8243I | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as COSV67464293; called by muse, mutect2
- MUC16 | c.16177C>T p.P5393S | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV67448841; called by muse, mutect2
- MUC16 | c.5513C>T p.A1838V | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs752594278; called by muse, mutect2, varscan2
- MUC4 | c.5435C>T p.T1812I | Missense Mutation (SNP) | VAF 69/570 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); catalogued as rs778219820; called by muse, mutect2, varscan2
- MXRA5 | c.2300C>G p.S767C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1304766566, COSV54231807; called by muse, varscan2
- MYBL2 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs766524660; called by muse, mutect2, varscan2
- MYH13 | c.4084C>T p.Q1362* | Nonsense Mutation (SNP) | VAF 101/457 reads (22%) | catalogued as rs199890413; called by muse, mutect2, varscan2
- MYH6 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100676302; called by muse, varscan2
- MYLIP | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 35/411 reads (9%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.453); catalogued as rs1008408548; called by muse, mutect2
- MYLK2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV65659898; called by muse, mutect2, varscan2
- MYO15A | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV52752101; called by muse, mutect2, varscan2
- MYO15A | c.9951C>T p.V3317= | Splice Region (SNP) | VAF 54/465 reads (12%) | catalogued as rs780864387; called by muse, mutect2, varscan2
- MYO5B | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs777222341; called by muse, mutect2
- MYOCD | c.591+1G>A p.X197_splice | Splice Site (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100590864; called by muse, mutect2, varscan2
- MYT1 | c.2081G>A p.G694D | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as rs756892784; called by muse, mutect2
- NAPSA | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364607909; called by muse, mutect2, varscan2
- NAV2 | c.2957G>A p.R986Q (on ENST00000396087 / NM_001244963.2; = p.R963Q on NM_145117.5) | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs752704652; called by muse, varscan2
- NAV3 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1174362847; called by muse, mutect2
- NBEAL1 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV71374086; called by muse, mutect2
- NBPF12 | c.3484C>T p.L1162F | Missense Mutation (SNP) | VAF 58/644 reads (9%) | SIFT tolerated (0.73); catalogued as COSV58770132; called by muse, mutect2
- NBPF9 | c.2663C>T p.S888L | Missense Mutation (SNP) | VAF 98/533 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs79474112; called by muse, mutect2, varscan2
- NCAPD2 | c.3538G>A p.G1180R | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1472426192; called by muse, mutect2, varscan2
- NCOR1 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); catalogued as COSV51985817, COSV51989049; called by muse, mutect2, varscan2
- NDNF | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.871); catalogued as rs781717177, COSV65633451; called by muse, mutect2, varscan2
- NDUFS2 | c.1116+1G>A p.X372_splice | Splice Site (SNP) | VAF 35/318 reads (11%) | catalogued as rs1459618345; called by muse, mutect2, varscan2
- NEB | c.18589G>A p.D6197N | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1364424120; called by muse, varscan2
- NECTIN3 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV60551292, COSV60552039; called by muse, mutect2, varscan2
- NEFM | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 76/358 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs890611466; called by muse, mutect2, varscan2
- NEK2 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs766897728; called by muse, mutect2
- NEK5 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769520527; called by muse, mutect2
- NEK8 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV99262089; called by muse, mutect2
- NEO1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV56066984; called by muse, mutect2
- NEO1 | c.4250C>T p.P1417L | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369017263; called by muse, mutect2
- NES | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs765528071, COSV63961646; called by muse, mutect2, varscan2
- NEURL3 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 29/336 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1558598143, COSV100182432; called by muse, mutect2
- NEUROD6 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99773832; called by muse, mutect2
- NF1 | c.60+1G>A p.X20_splice | Splice Site (SNP) | VAF 64/312 reads (21%) | catalogued as CD147189, CS076633, COSV62199447; called by muse, varscan2
- NF1 | c.6686G>A p.W2229* (on ENST00000358273 / NM_001042492.3; = p.W2208* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 38/395 reads (10%) | catalogued as CM143464; called by muse, mutect2
- NFKBID | c.7G>A p.A3T (on ENST00000396901; = p.A155T on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs775054726; called by muse, mutect2
- NFYC | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.457); catalogued as rs1418852224; called by muse, mutect2, varscan2
- NHLH1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 99/407 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57483744; called by muse, mutect2, varscan2
- NINL | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV54002253; called by muse, mutect2
- NLRP14 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55063778; called by muse, mutect2, varscan2
- NLRP5 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); catalogued as rs760289445; called by muse, mutect2, varscan2
- NME1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 136/750 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV50148136; called by muse, mutect2, varscan2
- NMT1 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766531390; called by muse, mutect2, varscan2
- NOG | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs1039686376; called by muse, mutect2, varscan2
- NOM1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1390308081; called by muse, mutect2
- NOM1 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51981585; called by muse, mutect2, varscan2
- NOTCH2 | c.4826C>T p.S1609F | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs866874822, COSV56688725; called by muse, mutect2
- NOTCH4 | c.5720G>A p.G1907E | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as rs774201468; called by muse, mutect2, varscan2
- NOXO1 | c.825G>A p.W275* (on ENST00000397280 / NM_172168.3; = p.W269* on NM_144603.4) | Nonsense Mutation (SNP) | VAF 35/569 reads (6%) | catalogued as rs1372148582; called by muse, mutect2
- NPAP1 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1484594194, COSV61504140; called by muse, mutect2, varscan2
- NPAS1 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs1243196097; called by muse, mutect2
- NPRL3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.899); catalogued as rs745987603; called by muse, mutect2, varscan2
- NR2E3 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs754661615; called by muse, mutect2, varscan2
- NR3C2 | c.2785G>A p.D929N | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60997042; called by muse, mutect2
- NRCAM | c.2788G>A p.V930M (on ENST00000379028 / NM_001371124.1; = p.V914M on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/496 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1480606027; called by muse, mutect2
- NRG2 | c.1565G>A p.S522N | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1242667168; called by muse, mutect2
- NRSN2 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 68/311 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV66526854; called by muse, mutect2, varscan2
- NRXN1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 90/464 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.517); catalogued as COSV68046776; called by muse, varscan2
- NTRK3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 31/357 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV58124226; called by muse, mutect2
- NVL | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV55873370, COSV55875653; called by muse, mutect2, varscan2
- NWD1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.637); catalogued as rs867793000; called by muse, mutect2, varscan2
- NYAP1 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 59/343 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs1371451867; called by muse, mutect2, varscan2
- OBI1 | c.300+1G>A p.X100_splice | Splice Site (SNP) | VAF 12/103 reads (12%) | catalogued as rs1418544333; called by muse, mutect2, varscan2
- OCA2 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 33/430 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.327); catalogued as rs868535053; called by muse, mutect2
- OPLAH | c.1919G>A p.G640D | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV70677107; called by muse, mutect2, varscan2
- OR10J1 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1198476429; called by muse, mutect2
- OR12D2 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV65827858; called by muse, mutect2
- OR1F1 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs868134628; called by muse, mutect2, varscan2
- OR2K2 | c.398C>T p.S133F (on ENST00000374428; = p.S104F on NM_205859.2) | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV57018519; called by muse, mutect2, varscan2
- OR4C15 | c.349G>A p.G117S (on ENST00000314644; = p.G63S on NM_001001920.2) | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); catalogued as COSV58956588; called by muse, mutect2, varscan2
- OR4D11 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV57585596; called by muse, mutect2, varscan2
- OR52L1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV59989072; called by muse, mutect2, varscan2
- OR5B2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1446437478; called by muse, mutect2
- OR5W2 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60614774, COSV60615520; called by muse, mutect2, varscan2
- OR7A5 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as rs951017608; called by muse, mutect2
- OSMR | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1208559994; called by muse, mutect2, varscan2
- OTOA | c.120+1G>A p.X40_splice | Splice Site (SNP) | VAF 34/454 reads (7%) | catalogued as rs1325436445; called by muse, mutect2
- OXER1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs749642199; called by muse, mutect2, varscan2
- OXTR | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.024); catalogued as rs1199625461; called by muse, mutect2
- PABPC3 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55796922; called by muse, mutect2
- PAICS | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | PolyPhen benign (0.268); catalogued as rs1364600243; called by muse, mutect2, varscan2
- PAM | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1023910255; called by muse, mutect2, varscan2
- PARP4 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV67960781; called by muse, mutect2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 54/443 reads (12%) | catalogued as rs756801119; called by mutect2, varscan2
- PAX6 | c.142-8C>T | Splice Region (SNP) | VAF 83/369 reads (22%) | catalogued as rs886048203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PBRM1 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs758198630, COSV56311783; called by muse, mutect2, varscan2
- PBX3 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.014); catalogued as rs542398925; called by muse, varscan2
- PCDHA12 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as COSV56534021; called by muse, mutect2
- PCDHA3 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs148196865, COSV63538858; called by muse, mutect2, varscan2
- PCDHB10 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782048683; called by muse, mutect2, varscan2
- PCDHB3 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 203/806 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.823); catalogued as rs781988108; called by muse, mutect2, varscan2
- PCLO | c.14497G>A p.D4833N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1382885046, COSV61629872; called by muse, mutect2
- PCLO | c.13139C>T p.P4380L | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440332; called by muse, mutect2, varscan2
- PCLO | c.8063G>A p.S2688N | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs1003433778; called by muse, mutect2, varscan2
- PCLO | c.7130C>T p.P2377L | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1562880305; called by muse, mutect2
- PCNX3 | c.3265G>A p.A1089T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.037); catalogued as rs377764546; called by muse, mutect2, varscan2
- PCSK1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.031); catalogued as COSV60736845; called by muse, mutect2, varscan2
- PCSK5 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1220824735; called by muse, mutect2, varscan2
- PCSK9 | c.1682-1G>A p.X561_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | catalogued as COSV99598899; called by muse, mutect2
- PDCD11 | c.3224G>A p.G1075D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100874427; called by muse, mutect2
- PDCD11 | c.4120G>A p.G1374R | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100874387; called by muse, mutect2, varscan2
- PDE1B | c.1267+1G>A p.X423_splice | Splice Site (SNP) | VAF 13/127 reads (10%) | catalogued as COSV54489651; called by muse, mutect2, varscan2
- PDILT | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.575); catalogued as rs755098526; called by muse, mutect2, varscan2
- PDK4 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV99138965; called by muse, mutect2
- PEX6 | c.2240G>A p.G747D | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362080429; called by muse, mutect2
- PFKL | c.639G>A p.G213= | Splice Region (SNP) | VAF 18/136 reads (13%) | catalogued as COSV100827315; called by muse, mutect2, varscan2
- PFKP | c.1389G>A p.W463* | Nonsense Mutation (SNP) | VAF 20/193 reads (10%) | catalogued as COSV66898838; called by muse, mutect2
- PGGT1B | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56972995; called by muse, mutect2
- PGGT1B | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56973672; called by muse, mutect2, varscan2
- PI4KA | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV55408568; called by muse, mutect2
- PIBF1 | c.1097G>A p.R366K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1316381694; called by muse, mutect2
- PID1 | c.554G>A p.R185K (on ENST00000354069 / NM_001330156.1; = p.R183K on NM_017933.5) | Missense Mutation (SNP) | VAF 91/468 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs868845353, COSV62484078; called by muse, mutect2, varscan2
- PIGG | c.1595G>A p.G532D (on ENST00000453061 / NM_001127178.3; = p.G524D on NM_017733.4) | Missense Mutation (SNP) | VAF 95/430 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs753841067; called by muse, mutect2, varscan2
- PIGM | c.851G>A p.S284N | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs374754962; called by muse, mutect2, varscan2
- PIK3R1 | c.1931G>A p.G644D (on ENST00000521381 / NM_181523.3; = p.G374D on NM_181504.4) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57126472, COSV99144926; called by muse, mutect2, varscan2
- PINK1 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 105/442 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58631903; called by muse, mutect2, varscan2
- PITPNM1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs776940244, COSV62709727; called by muse, mutect2, varscan2
- PIWIL1 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as COSV55346593; called by muse, mutect2, varscan2
- PIWIL3 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.877); catalogued as rs187027471, COSV59995336; called by muse, mutect2
- PKD1 | c.7577G>A p.C2526Y | Missense Mutation (SNP) | VAF 67/837 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.517); catalogued as COSV51925694; called by muse, mutect2
- PKD1L2 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1193565770, COSV61420486; called by muse, varscan2
- PKD2L2 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV51801480; called by muse, mutect2, varscan2
- PKHD1L1 | c.6076C>T p.P2026S | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.673); catalogued as COSV65748468; called by muse, mutect2
- PKLR | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 95/477 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs370316462, CM950962; called by muse, mutect2, varscan2
- PKP2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 107/532 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as CM1313303; called by muse, mutect2, varscan2
- PLA2G6 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.686); catalogued as rs1407292338; called by muse, mutect2, varscan2
- PLBD2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.154); catalogued as COSV55106252; called by muse, varscan2
- PLCH2 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.028); catalogued as rs1281461797; called by muse, mutect2
- PLEC | c.13502C>T p.T4501I (on ENST00000322810 / NM_201380.4; = p.T4391I on NM_000445.5) | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs1208514926; called by muse, mutect2
- PLEKHG3 | c.1796G>A p.G599D (on ENST00000394691; = p.G655D on NM_001308147.2) | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs1566717103, COSV55978552; called by muse, mutect2
- PLEKHH3 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99511667; called by muse, mutect2, varscan2
- PLK1 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs758643617; called by muse, mutect2, varscan2
- PLXNA3 | c.4538C>T p.T1513I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1259860516, COSV63754762; called by muse, mutect2, varscan2
- PNLIPRP3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs373999631; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57965521; called by muse, mutect2, varscan2
- POSTN | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101123378, COSV65713570; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs768050754; called by muse, mutect2, varscan2
- PPIL6 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354923545; called by muse, mutect2, varscan2
- PPP1CC | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV100534802; called by muse, mutect2
- PPP1R14C | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 37/350 reads (11%) | catalogued as rs1261904273; called by muse, mutect2
- PPP1R3A | c.1628G>A p.R543K | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.3); catalogued as COSV52880421; called by muse, mutect2
- PRKAG2 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV55222754; called by muse, mutect2
- PRKDC | c.4160G>A p.G1387E | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV58054615; called by muse, mutect2
- PRM3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as rs1284035953; called by muse, mutect2, varscan2
- PRODH2 | c.1603C>T p.P535S (on ENST00000301175; = p.P459S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV56561254; called by muse, mutect2
- PROSER1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61490016; called by muse, mutect2
- PRPF31 | c.1073+6G>A | Splice Region (SNP) | VAF 23/174 reads (13%) | catalogued as rs765404848; called by muse, mutect2, varscan2
- PRR22 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs759158049; called by muse, mutect2, varscan2
- PRRC2B | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV61941606; called by muse, mutect2
- PRRT3 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV55976208; called by muse, mutect2, varscan2
- PRSS38 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 39/440 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750175996; called by muse, mutect2
- PSAPL1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59842535; called by muse, mutect2
- PSMD2 | c.1539G>A p.E513= | Splice Region (SNP) | VAF 32/160 reads (20%) | catalogued as rs747748170; called by muse, mutect2, varscan2
- PSME4 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as rs934272409, COSV66362998; called by muse, mutect2, varscan2
- PTBP3 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 29/163 reads (18%) | catalogued as COSV52958390; called by muse, mutect2, varscan2
- PTGER2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.227); catalogued as rs1265519374; called by muse, mutect2, varscan2
- PTGIS | c.378G>A p.L126= | Splice Region (SNP) | VAF 14/195 reads (7%) | catalogued as rs967489527; called by muse, mutect2
- PTPRQ | c.3415C>T p.R1139C (on ENST00000616559; = p.R1097C on NM_001145026.2) | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs951616671; called by muse, mutect2, varscan2
- PURB | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 8/110 reads (7%) | catalogued as rs1387376324; called by muse, mutect2
- QARS1 | c.1896G>A p.W632* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as rs753463624; called by muse, mutect2, varscan2
- QRICH1 | c.2047G>A p.V683I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV58707712; called by muse, mutect2
- QRICH2 | c.4447G>A p.G1483S | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs1240717455; called by muse, mutect2
- RAG1 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100200638; called by muse, mutect2, varscan2
- RANBP2 | c.3851G>A p.R1284K | Missense Mutation (SNP) | VAF 162/767 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV99311918; called by muse, mutect2, varscan2
- RANBP2 | c.6187C>T p.L2063F | Missense Mutation (SNP) | VAF 61/653 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51706106; called by muse, mutect2, varscan2
- RAPGEFL1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.988); catalogued as rs1334000386; called by muse, mutect2, varscan2
- RARS2 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101057011; called by muse, mutect2, varscan2
- RASA2 | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs769631893; called by muse, mutect2, varscan2
- RASIP1 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.283); catalogued as rs1292118325; called by muse, mutect2, varscan2
- RBM28 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 52/743 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1409235872; called by muse, mutect2
- RBM39 | c.1192G>A p.D398N (on ENST00000253363 / NM_001323424.2; = p.X392_splice on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.857); catalogued as COSV53618806, COSV99488897; called by muse, varscan2
- RBP3 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs1555211388; called by muse, mutect2, varscan2
- RCN1 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs1023202519; called by muse, mutect2, varscan2
- RECQL4 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 34/411 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.049); catalogued as rs1319378486; called by muse, mutect2
- RECQL5 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV53126926; called by muse, mutect2, varscan2
- RELB | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1038365209; called by muse, mutect2
- RELN | c.9357G>A p.M3119I | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.854); catalogued as COSV59009100; called by muse, mutect2
- REPIN1 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 48/479 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1226249166; called by muse, mutect2, varscan2
- RGL1 | c.1594C>T p.P532S (on ENST00000360851 / NM_001297672.2; = p.P567S on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745474593; called by muse, mutect2
- RGS4 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63358048; called by muse, mutect2
- RGS7BP | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as rs773845244; called by muse, mutect2, varscan2
- RGS9 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 66/484 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771246224; called by muse, mutect2, varscan2
- RHBDD2 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as rs1554544484, COSV99138189; called by muse, mutect2
- RNASEH1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1266318997; called by muse, mutect2
- RP1L1 | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 36/405 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV66760988; called by muse, mutect2
- RP9 | c.313+3G>A | Splice Region (SNP) | VAF 38/452 reads (8%) | catalogued as rs1187117825; called by muse, mutect2
- RPGRIP1L | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100046943; called by muse, mutect2, varscan2
- RPH3AL | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777184439; called by muse, mutect2
- RPN2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 106/539 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as rs1279812710, COSV52909239; called by muse, mutect2, varscan2
- RPS6KC1 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344616472; called by muse, mutect2, varscan2
- RRP9 | c.390+1G>A p.X130_splice | Splice Site (SNP) | VAF 73/335 reads (22%) | catalogued as rs1199338128; called by muse, mutect2, varscan2
4,309 further variants in this file (2,217 protein-altering or splice-affecting, 1,427 silent, 665 other) are not listed here.
